TCGA case TCGA-AA-3510 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/35c295c2-37d1-44b2-87a3-1039645e5bae

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Age at diagnosis: 70.9 years (25,902 days); Year of diagnosis: 2005; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,946 days (5.3 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 44; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 31 days; Disease response: With Tumor.
- Days to follow up: 1,946 days (5.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 3.59 ng/mL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-AA-3510-01A-01-TS1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-AA-3510-01A-01-BS1: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 15; Percent stromal cells: 5.
- Sample TCGA-AA-3510-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3510-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 3.59; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,946 days; disease-specific survival: no event (censored), 1,946 days; disease-free interval: no event (censored), 1,946 days; progression-free interval: no event (censored), 1,946 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3510-01A-01D-1406-01): tumor purity 0.58, ploidy 2, whole-genome doublings 0.
